Surgical pathology report (de-identified scan), TCGA case TCGA-19-5950, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Case Western, specimen TCGA-19-5950-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT
Addendum Present

FINAL DIAGNOSIS

TCGA-19-5950

A. MEDIAL TEMPORAL LOBE OF BRAIN, TUMOR, REMOVAL:

- MALIGNANT SMALL CELL GLIOMA, CONSISTENT WITH DERIVATION FROM SMALL CELL GLIOBLASTOMA MULTIFORME; SEE NOTE.
- EXTENSIVE COAGULATIVE NECROSIS WITH PERIVENULAR INFLAMMATION, CONSISTENT WITH PRIOR SURGICAL RESECTION.

Note: An addendum will be issued pending analyses for deletions in chromosomes 1p and 19q and epidermal growth factor receptor amplification.

B. TEMPORAL TIP, REMOVAL:

- MILD WHITE MATTER HYPERCELLULARITY, CONSISTENT WITH INFILTRATING GLIOMA.

Electronically Signed Out By

By the signature on this report, the individual or group listed as making the Final Interpretation/Diagnosis certifies that they have reviewed this case.

Addendum/Procedures:

ANCILLARY TESTING

Date Ordered:
Date Complete:
Date Reported:

Status: Signed Out

Results-Comments

EGFR MUTATION ANALYSIS

Date Ordered:
Date Completed:
Specimen Source:
Paraffin Block No.:

MEDIAL TEMPORAL TUMOR TISSUE

TUMOR TISSUE ASSESSMENT

RESULTS: NO EGFR ALTERATIONS DETECTED

Genotype Results: WILD-TYPE (NO EGFR ALTERATIONS DETECTED)

INTERPRETATION:

Reference Ranges:

Alteration Detected: See Comment

Alteration Not Detected

COMMENT:

Methodology: Tumor areas of interest were identified and selectively microdissected from the paraffin-embedded tissue section. The collected cells were lysed, and the genomic DNA was purified from the sample. The DNA yield was determined, and the samples were brought to an optimal concentration. Real-time PCR was used to evaluate specific mutations, deletions and insertions in the tyrosine kinase domain of the Epidermal Growth Factor (EGFR) gene. Eight reactions containing 30 primer and probe

[page 2 of 2]
sets were used to target specific regions of exons 18-21 as well as the wild-type sequence.

Intended Use: The EGFR mutation analysis by real-time PCR is able to detect the wild type sequence and 29 known mutations, deletions and insertions found in exons 18-21 of the EGFR tyrosine kinase domain. The results of this study are to be interpreted in context with other clinical findings in patient care management. The intended use of this assay is to aid the treating physician in the selection of the appropriate therapy for the patient.

There is a significant association between EGFR mutation, especially exon 19 deletion, and the response to TKI's. These mutations are linked to clinical responsiveness to EGFR inhibitors, such as gefitinib (Iressa) and erlotinib (Tarceva).

This assay was developed and its performance characteristics were determined by [REDACTED]. Pursuant to the requirements of [REDACTED], this laboratory has established the test's accuracy and precision. It has not been cleared or approved by the U.S. Food and Drug Administration, as the FDA has determined that such approval is not necessary. This test is used for clinical purposes. The results of this study are to be interpreted in the context of all other clinical findings. A copy of their report is retained in the records of the [REDACTED].

Electronically Signed Out By [REDACTED]

Addendum

Date Ordered: [REDACTED]
Date Complete: [REDACTED]
Date Reported: [REDACTED]

Status: Signed Out

Addendum Diagnosis

Fluorescence in situ hybridization, performed at [REDACTED], demonstrates loss of chromosome 1p and preservation of chromosome 19q.

Electronically Signed Out By [REDACTED]

Clinical History:

gbm

Specimens Submitted As:

A: MEDIAL TEMPORAL TUMOR
B: TEMPORAL TIP

Gross Description:

A: Received in formalin, labeled with the patient's name and number, are four light tan to tan-gray soft cerebriform tissue fragments ranging from 1.0 x 0.8 x 0.4 cm to 3.5 x 3.2 x 2.3 cm. On section, the fragment is light tan to tan-gray. A portion was given to [REDACTED] by the frozen section room prior to measurements being obtained. Submitted entirely in seven cassettes.

B: Received in formalin, labeled with the patient's name and number, is one light tan to tan-gray soft cerebriform tissue fragment measuring 3.3 x 1.7 x 0.8 cm. On section, the fragment is light tan to tan-gray. A portion was given to [REDACTED] by the frozen section room prior to measurements being obtained. Submitted entirely in four cassettes.

Source: NCI Genomic Data Commons file 53759b96-693a-444f-adeb-3fb3121a2447 (TCGA-19-5950.ED8BA394-7042-4DE1-8E08-1FF92DB2B544.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).